Somatic mutation profile of tumor specimen TCGA-06-0174-01A (aliquot TCGA-06-0174-01A-01D-1491-08) from TCGA case TCGA-06-0174, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.3 years (19,824 days).
Specimen TCGA-06-0174-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78ebc82e-72cd-4c52-87b8-908e35406689.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0174-10B (Blood Derived Normal), aliquot TCGA-06-0174-10B-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b53a053-6f6f-4af2-a1ef-24f78cf00bd6

The open-access MAF lists 71 somatic variants for this specimen: 55 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 49, Silent 16, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACYP1 | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 140/373 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV53134549; called by muse, mutect2, varscan2
- AFF2 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 272/310 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV53977639; called by muse, mutect2, varscan2
- AMELX | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.035); catalogued as rs148259441, COSV61624324, COSV61629939, COSV61636382; called by muse, mutect2
- ARMC4 | c.1950T>G p.I650M | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59456666; called by muse, mutect2, varscan2
- ASNSD1 | c.1087A>G p.M363V | Missense Mutation (SNP) | VAF 84/153 reads (55%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV53622988; called by muse, mutect2, varscan2
- BBS9 | c.1561C>T p.R521* (on ENST00000242067 / NM_001348036.1; = p.R481* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 98/381 reads (26%) | catalogued as rs748601675, COSV54157359; called by muse, varscan2
- BCDIN3D | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61702217; called by muse, mutect2, varscan2
- BICD1 | c.2719G>C p.G907R | Missense Mutation (SNP) | VAF 90/210 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.755); catalogued as COSV55674996; called by muse, mutect2, varscan2
- CCDC34 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.077); catalogued as COSV100156403; called by muse, mutect2, varscan2
- CCT5 | c.1240C>A p.R414S | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV54723239, COSV54723403; called by muse, mutect2, varscan2
- CD4 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50589166; called by muse, mutect2
- CEP131 | c.1783G>A p.A595T (on ENST00000269392 / NM_001319228.2; = p.A592T on NM_014984.4) | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.151); catalogued as COSV53950862; called by muse, mutect2, varscan2
- CLMP | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 175/416 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV71649287; called by muse, mutect2, varscan2
- CPSF6 | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 170/282 reads (60%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV57012400, COSV57014857; called by muse, mutect2, varscan2
- CYP2S1 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs199728850, COSV59505104; called by muse, mutect2, varscan2
- DCAF12L2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV63580392, COSV63581113; called by muse, mutect2, varscan2
- DERL3 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV51954308; called by muse, mutect2, varscan2
- DNTT | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 136/156 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747158808, COSV64522656; called by muse, mutect2, varscan2
- DOCK5 | c.2143G>A p.V715I | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV52396395; called by muse, mutect2, varscan2
- ELAPOR2 | c.1470C>A p.N490K (on ENST00000450689 / NM_001142749.3; = p.N323K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV51884246; called by muse, mutect2, varscan2
- GIPC2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143579527; called by muse, mutect2, varscan2
- GTF3C1 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 71/162 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs773213449, COSV100649695, COSV62238787; called by muse, mutect2, varscan2
- HECTD1 | c.5992del p.E1998Kfs*12 | Frame Shift Del (DEL) | VAF 186/484 reads (38%) | catalogued as COSV67946241; called by mutect2, pindel, varscan2
- HYDIN | c.6985C>T p.R2329W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762688293, COSV99992144; called by mutect2, varscan2
- JPH1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs748452859, COSV60608792; called by muse, mutect2, varscan2
- LRRC52 | c.732C>A p.D244E | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54231340; called by muse, mutect2, varscan2
- MAPKBP1 | c.2307C>T p.N769= (on ENST00000456763 / NM_001128608.2; = p.N763= on NM_014994.3) | Splice Region (SNP) | VAF 41/95 reads (43%) | catalogued as rs753204423, COSV52958360; called by muse, mutect2, varscan2
- MFSD6L | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 92/250 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as COSV61001442; called by muse, mutect2
- OR13A1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 54/68 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1564532733, COSV65571982; called by muse, mutect2, varscan2
- OTOA | c.17C>T p.T6M | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as rs144912852; called by muse, mutect2, varscan2
- PAX2 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 112/126 reads (89%) | catalogued as CM076374, COSV62290216, COSV62293591; called by muse, mutect2, varscan2
- PCDHGB5 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.274); catalogued as rs946281582, COSV53903531; called by muse, mutect2, varscan2
- PDGFRA | c.1047G>C p.W349C | Missense Mutation (SNP) | VAF 1973/2803 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57265030; called by muse, mutect2, varscan2
- PKP4 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.135); catalogued as rs374838936; called by muse, varscan2
- RANBP17 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as rs369051193; called by muse, mutect2, varscan2
- RPL10L | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1442599187, COSV53558705; called by muse, varscan2
- RTL4 | c.356G>C p.S119T | Missense Mutation (SNP) | VAF 108/116 reads (93%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as COSV61205639; called by muse, mutect2, varscan2
- SELE | c.773A>G p.N258S | Missense Mutation (SNP) | VAF 135/297 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV60974020; called by muse, mutect2, varscan2
- SLC9A4 | c.2311G>T p.V771F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV54829277; called by muse, mutect2, varscan2
- ST18 | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52485147; called by muse, mutect2, varscan2
- STPG1 | c.216C>A p.Y72* (on ENST00000337248 / NM_001199013.2; = p.Y25* on NM_178122.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/259 reads (4%) | catalogued as COSV50217812; called by muse, mutect2
- SVOPL | c.814C>A p.L272I (on ENST00000419765; = p.L120I on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/260 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55988557; called by muse, mutect2, varscan2
- SYN3 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs753833714, COSV60502626; called by mutect2, varscan2
- TEX15 | c.5786A>G p.Q1929R (on ENST00000256246; = p.Q2312R on NM_001350162.2) | Missense Mutation (SNP) | VAF 68/181 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as COSV56342026; called by muse, mutect2, varscan2
- TGIF2LY | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 118/143 reads (83%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs779833813, COSV58291544; called by muse, mutect2, varscan2
- TMC5 | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 162/408 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.492); catalogued as rs763397362, COSV66864559; called by muse, mutect2, varscan2
- TNFRSF4 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1269060561, COSV55417753; called by muse, mutect2, varscan2
- TRIM71 | c.2345G>A p.R782H | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs373870640; called by muse, mutect2, varscan2
- TRPS1 | c.1510G>C p.G504R (on ENST00000220888 / NM_001330599.2; = p.G517R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/253 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as COSV55227720; called by muse, mutect2, varscan2
- UFSP2 | c.781A>G p.I261V | Missense Mutation (SNP) | VAF 130/264 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV52990623; called by muse, mutect2, varscan2
- UNC45B | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 158/284 reads (56%) | SIFT tolerated (0.8); PolyPhen benign (0.013); catalogued as rs543327883, COSV52092506; called by muse, mutect2, varscan2
- VAV2 | c.1342G>A p.E448K (on ENST00000371850 / NM_001134398.2; = p.E443K on NM_003371.4) | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV64080224; called by muse, mutect2, varscan2
- VSTM2A | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV56492348; called by muse, mutect2, varscan2
- ZMYM5 | c.1093T>C p.C365R | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61987370; called by muse, mutect2, varscan2
- STRN | c.819_838del p.D274Yfs*9 | Frame Shift Del (DEL) | VAF 64/243 reads (26%) | called by mutect2, pindel, varscan2
- CNTN4 | c.438G>A p.P146= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as rs1281255689, COSV68563395; called by muse, mutect2, varscan2
- CPA6 | c.1191C>T p.F397= | Silent (SNP) | VAF 76/172 reads (44%) | catalogued as rs760234221, COSV52721280; called by muse, varscan2
- EPDR1 | c.519T>C p.Y173= | Silent (SNP) | VAF 28/167 reads (17%) | catalogued as COSV52258314; called by muse, mutect2, varscan2
- FAM200A | c.36T>G p.S12= | Silent (SNP) | VAF 65/209 reads (31%) | catalogued as COSV68808569; called by muse, mutect2, varscan2
- FBXO24 | c.1242C>T p.C414= (on ENST00000241071 / NM_033506.3; = p.C452= on NM_012172.5) | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs772661530, COSV53823788; called by muse, mutect2, varscan2
- NAGA | c.870C>T p.S290= | Silent (SNP) | VAF 69/194 reads (36%) | catalogued as rs144984228; called by muse, mutect2, varscan2
- P3H1 | c.1830C>T p.R610= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs780329868, COSV52531860, COSV52536741; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHA11 | c.1608G>A p.A536= | Silent (SNP) | VAF 40/186 reads (22%) | catalogued as COSV56479661; called by muse, mutect2, varscan2
- PKHD1 | c.3891G>A p.A1297= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as rs775529923, COSV61861883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR3C | c.1392T>A p.S464= | Silent (SNP) | VAF 80/177 reads (45%) | catalogued as COSV57906729; called by muse, mutect2, varscan2
- RYR1 | c.3267C>T p.F1089= | Silent (SNP) | VAF 65/250 reads (26%) | catalogued as rs1302567016, COSV100615171, COSV62089673; called by muse, mutect2, varscan2
- SCN4A | c.3150C>T p.F1050= | Silent (SNP) | VAF 25/51 reads (49%) | catalogued as rs536963836, COSV71125690; called by muse, mutect2, varscan2
- SNX18 | c.1482C>G p.A494= | Silent (SNP) | VAF 58/127 reads (46%) | catalogued as COSV57987728; called by muse, mutect2, varscan2
- TMEM132B | c.1224C>T p.V408= | Silent (SNP) | VAF 86/184 reads (47%) | catalogued as COSV54745428; called by muse, mutect2, varscan2
- TRBV20-1 | c.114T>C p.R38= | Silent (SNP) | VAF 83/267 reads (31%) | called by muse, mutect2, varscan2
- XDH | c.1785C>T p.D595= | Silent (SNP) | VAF 203/458 reads (44%) | catalogued as rs140066757; called by muse, mutect2, varscan2
